Somatic mutation profile of tumor specimen 0DJC3A from CCDI case PBBWLY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebrum; Age at diagnosis: 15.7 years (5,744 days).
Specimen 0DJC3A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57fb4b4f-4ea4-4e39-a8af-7a905f371878.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJBLQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94b9bf04-1ffa-44f9-87dc-1ced17e5fba7

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 1, Silent 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGA7B | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 98/345 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.414); catalogued as rs200719626, COSV65428783; called by muse, mutect2, varscan2
- RGPD3 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1367903490; called by mutect2, varscan2
- RNF220 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 35/281 reads (12%) | catalogued as COSV62404815; called by muse, mutect2, varscan2
- TG | c.7465C>T p.R2489C | Missense Mutation (SNP) | VAF 116/271 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs778353394, COSV55065560; called by muse, mutect2, varscan2
- TTC6 | c.1061G>A p.R354H (on ENST00000267368; = p.R1720H on NM_001310135.3) | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs143675181, COSV99941628; called by muse, mutect2, varscan2
- ZNF131 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs752500805; called by muse, mutect2, varscan2
- ZP1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 231/543 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs760618120; called by muse, mutect2, varscan2
- SLC12A5 | c.2402A>G p.N801S (on ENST00000454036 / NM_001134771.2; = p.N778S on NM_020708.5) | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBC1D12 | c.774_776del p.G259del | In Frame Del (DEL) | VAF 81/200 reads (41%) | called by mutect2, pindel, varscan2
- CHIT1 | c.1326G>A p.A442= | Silent (SNP) | VAF 157/395 reads (40%) | catalogued as rs186594769, COSV55147899; called by muse, mutect2, varscan2
- UHRF2 | c.1604+74dup | Intron (INS) | VAF 40/118 reads (34%) | called by mutect2, pindel, varscan2
